Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4781, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4781-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4781

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right renal tumor.

Specimens Submitted:

1: SP: Kidney, Right, partial nephrectomy

DIAGNOSIS:

1. SP: Kidney, Right, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with sarcomatoid features (10%)

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.2 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

N/A

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not Identified

Lymph Nodes:

Not Identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Right renal tumor, stitch marks deep margin". It consists of a partial nephrectomy specimen measuring 4.5 x 4.5 x 1.9 cm. A piece of irregular shaped flat fat attached with capsule surface measuring 4.5 x 2.5 x 0.3 cm. The deep surgical margin is inked black. The capsular margin is inked yellow. The fat is inked green. Frozen section was performed on surgical margin. Tissue submitted for TPS. Gross photographs taken. A segment of normal kidney attached with the specimen measuring 3.0 x 1.5 x 1.5 cm. The resection reveals a well-circumscribed mass measuring 3.2 x 2.5 x 1.5 cm. The tumor appears cystic with bright yellow and hemorrhagic cut surface. The cyst contains clear fluid. The cystic wall is thick and partially calcified. The tumor protrudes from the renal capsule into the adjacent fatty tissue, however there is no perinephric fat seen grossly.

Summary of Sections:

FSC-frozen section control

T - tumor

P - renal parenchyma

Summary of Sections:

Part 1: SP: Kidney, Right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	p	1
9	t	9

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: CONVENTIONAL/CLEAR CELL RENAL CELL CARCINOMA, MARGIN CLEAR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file a3a3a464-8527-40ec-ab0b-e482da6dee2e (TCGA-BP-4781.50AAF7BC-5445-4255-9752-4D6AC096AA50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).